Somatic mutation profile of cancer-model specimen HCM-CSHL-0247-C18-85M (3D Organoid; aliquot HCM-CSHL-0247-C18-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0247-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 76.5 years (27,936 days).
Specimen HCM-CSHL-0247-C18-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b52d4c87-4a66-4a90-9a41-25c38928eba7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0247-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0247-C18-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02abcc00-b2dc-4686-983a-9e73f93fc2c4

The open-access MAF lists 216 somatic variants for this specimen: 137 protein-altering or splice-affecting, 51 silent, 28 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 120, Silent 51, Intron 14, Nonsense Mutation 11, 3'UTR 5, 5'UTR 5, Frame Shift Del 3, Frame Shift Ins 3, 5'Flank 2, RNA 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AMER1 | c.1072C>T p.R358* | Nonsense Mutation (SNP) | VAF 97/97 reads (100%) | catalogued as rs137852217, CM090019, COSV57654223; ClinVar: pathogenic; called by muse, mutect2, varscan2
- APC | c.4348C>T p.R1450* | Nonsense Mutation (SNP) | VAF 35/78 reads (45%) | hotspot (GDC flag); catalogued as rs121913332, CM930030, COSV57321313; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.844); catalogued as rs121913527, COSV55501778, COSV55541748, COSV55727828; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- RAD50 | c.205G>A p.D69N | Missense Mutation (SNP) | VAF 7/48 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370769989, COSV54748170; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 551/552 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACSM1 | c.1022A>G p.Y341C | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs527828401; called by muse, mutect2, varscan2
- AL358113.1 | c.3914G>A p.R1305H | Missense Mutation (SNP) | VAF 262/569 reads (46%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.121); catalogued as rs1037430967, COSV61957022; called by muse, mutect2, varscan2
- ALPK3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 276/276 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.336); catalogued as COSV51940688; called by muse, mutect2, varscan2
- AMER3 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 20/171 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as COSV58470483; called by muse, mutect2, varscan2
- AP1M2 | c.748G>A p.D250N | Missense Mutation (SNP) | VAF 96/220 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); catalogued as rs761767257; called by muse, mutect2, varscan2
- ASAP1 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 114/289 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.383); catalogued as rs1365555616; called by muse, mutect2, varscan2
- ASCL4 | c.472G>T p.A158S | Missense Mutation (SNP) | VAF 18/29 reads (62%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); catalogued as rs759654010; called by muse, varscan2
- ATRNL1 | c.2932C>T p.R978W | Missense Mutation (SNP) | VAF 10/244 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781789541, COSV58092954; called by muse, mutect2
- CACNA1A | c.1813G>A p.V605I | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as rs756562814, COSV64200832, COSV64211473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAP2 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 91/178 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as rs200521747, COSV57731947; called by muse, mutect2, varscan2
- CCDC116 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs200982664; called by muse, mutect2, varscan2
- CDH23 | c.4519C>T p.R1507W | Missense Mutation (SNP) | VAF 169/294 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as rs760927863, COSV56477037; called by muse, mutect2, varscan2
- CDH7 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59880968; called by muse, mutect2, varscan2
- CNTN5 | c.233C>T p.S78F | Missense Mutation (SNP) | VAF 112/387 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.248); catalogued as rs1398463099, COSV54329471; called by muse, mutect2, varscan2
- COL4A2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 105/378 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs773576081; called by muse, mutect2, varscan2
- CPB1 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as rs150860615, COSV99294138; called by muse, mutect2, varscan2
- CSMD3 | c.5836C>A p.R1946S (on ENST00000297405 / NM_001363185.1; = p.R1842S on NM_052900.3) | Missense Mutation (SNP) | VAF 158/337 reads (47%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.775); catalogued as rs377290204; called by muse, mutect2, varscan2
- DIPK1B | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 187/453 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs770330516, COSV63038081; called by muse, mutect2, varscan2
- EIF2B5 | c.1630G>A p.E544K (on ENST00000647909; = p.E536K on NM_003907.3) | Missense Mutation (SNP) | VAF 173/415 reads (42%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); catalogued as COSV56605595; called by muse, mutect2, varscan2
- ERBB4 | c.1573C>T p.R525C | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.674); catalogued as rs775988789, COSV53516370, COSV99626233; called by muse, mutect2, varscan2
- FLG2 | c.4636C>A p.Q1546K | Missense Mutation (SNP) | VAF 16/302 reads (5%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.587); catalogued as COSV66167593; called by muse, mutect2
- GIMAP1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 24/253 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs1476231665; called by muse, mutect2
- GLI3 | c.2665G>A p.V889M | Missense Mutation (SNP) | VAF 223/775 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.576); catalogued as rs1296035859, COSV67890481; called by muse, varscan2
- GLI3 | c.2623C>T p.R875C | Missense Mutation (SNP) | VAF 571/822 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as rs755227076, COSV67887250; ClinVar: uncertain significance; called by muse, varscan2
- GRM3 | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 96/274 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs112122758, COSV100862026, COSV64478495; called by muse, mutect2, varscan2
- GTF2H4 | c.925G>A p.V309M | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs760294963; called by muse, mutect2, varscan2
- HLA-DOA | c.700G>A p.V234M | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.461); catalogued as rs200140467; called by muse, mutect2
- HPCAL1 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.113); catalogued as COSV57145974; called by muse, mutect2, varscan2
- HYDIN | c.2020G>C p.V674L | Missense Mutation (SNP) | VAF 61/200 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as rs778990675; called by muse, mutect2, varscan2
- LAMA2 | c.7537G>A p.D2513N | Missense Mutation (SNP) | VAF 72/328 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.027); catalogued as rs749794799; called by muse, mutect2, varscan2
- LAMB4 | c.2536C>T p.R846C | Missense Mutation (SNP) | VAF 48/553 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs375212601, COSV52723704; called by muse, mutect2
- MED12L | c.3280C>T p.R1094* | Nonsense Mutation (SNP) | VAF 23/127 reads (18%) | catalogued as COSV56380574; called by muse, mutect2, varscan2
- MNDA | c.340C>T p.P114S | Missense Mutation (SNP) | VAF 48/152 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.321); catalogued as rs1329858284; called by muse, varscan2
- MSLNL | c.1193C>T p.T398M | Missense Mutation (SNP) | VAF 127/248 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765899968, COSV53498896; called by muse, mutect2, varscan2
- MUC5B | c.10805G>A p.R3602H | Missense Mutation (SNP) | VAF 36/305 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs750558610; called by muse, mutect2, varscan2
- NAP1L3 | c.274T>A p.L92M | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.133); catalogued as COSV59078117; called by muse, varscan2
- NLRC5 | c.10G>A p.V4I | Missense Mutation (SNP) | VAF 36/101 reads (36%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs866090118, COSV52660803; called by muse, mutect2, varscan2
- NOL6 | c.788G>A p.R263H | Missense Mutation (SNP) | VAF 221/437 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs756516749; called by muse, mutect2, varscan2
- NUP107 | c.173C>G p.S58* | Nonsense Mutation (SNP) | VAF 15/95 reads (16%) | catalogued as COSV57495134; called by muse, mutect2, varscan2
- OR4N2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 139/491 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs770622276, COSV60050519; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.803G>A p.R268H (on ENST00000259318 / NM_001136562.3; = p.R499H on NM_007203.5) | Missense Mutation (SNP) | VAF 149/277 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs368590919; called by muse, mutect2, varscan2
- PCDHA12 | c.1726G>A p.A576T | Missense Mutation (SNP) | VAF 241/607 reads (40%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.024); catalogued as rs781787046, COSV56485542; called by muse, mutect2, varscan2
- PCDHAC1 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 11/147 reads (7%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.838); catalogued as rs782460713; called by muse, mutect2
- PCDHGA6 | c.2138C>T p.A713V | Missense Mutation (SNP) | VAF 299/530 reads (56%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.052); catalogued as rs919176873, COSV53913907; called by muse, mutect2, varscan2
- PRICKLE1 | c.1360G>A p.E454K | Missense Mutation (SNP) | VAF 93/382 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.026); catalogued as rs748454609, COSV58204414; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRRX1 | c.424T>A p.F142I | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV53417051, COSV99509340; called by muse, mutect2, varscan2
- PSKH2 | c.522G>T p.L174F | Missense Mutation (SNP) | VAF 28/258 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1175415629; called by muse, mutect2, varscan2
- RAG2 | c.1524dup p.G509Rfs*15 | Frame Shift Ins (INS) | VAF 35/275 reads (13%) | catalogued as rs751978214; called by mutect2, pindel, varscan2
- RIMBP2 | c.248C>T p.T83M | Missense Mutation (SNP) | VAF 89/146 reads (61%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as rs763832408; called by muse, mutect2, varscan2
- RNF2 | c.988G>A p.A330T | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as rs1335456103, COSV62279097; called by muse, mutect2, varscan2
- SERPINB2 | c.713G>A p.R238H | Missense Mutation (SNP) | VAF 21/21 reads (100%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs922692149, COSV55091465; called by muse, mutect2, varscan2
- SIN3A | c.2899C>T p.R967W | Missense Mutation (SNP) | VAF 112/112 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100845221; called by muse, mutect2, varscan2
- SLC6A2 | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 189/380 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs776659407, COSV54923884; called by muse, mutect2, varscan2
- SOX9 | c.1261_1267dup p.F423* | Frame Shift Ins (INS) | VAF 103/118 reads (87%) | catalogued as COSV55427921; called by mutect2, varscan2
- SYNE1 | c.22022G>T p.C7341F (on ENST00000367255 / NM_182961.4; = p.C7270F on NM_033071.3) | Missense Mutation (SNP) | VAF 19/164 reads (12%) | SIFT tolerated (0.7); PolyPhen benign (0.072); catalogued as COSV54910569; called by muse, mutect2, varscan2
- TBC1D31 | c.2588T>C p.M863T | Missense Mutation (SNP) | VAF 47/406 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs777076749; called by muse, mutect2, varscan2
- TENM2 | c.2416G>A p.E806K (on ENST00000518659 / NM_001122679.2; = p.E574K on NM_001080428.3) | Missense Mutation (SNP) | VAF 81/194 reads (42%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs376627738; called by muse, mutect2, varscan2
- TEPP | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.578); catalogued as rs192110404, COSV99333121; called by muse, mutect2, varscan2
- TMC3 | c.2881C>T p.R961C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.549); catalogued as rs1160659483, COSV63924077; called by muse, mutect2, varscan2
- TNXB | c.5065G>A p.G1689S (on ENST00000647633; = p.G1442S on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 197/388 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs762480960; called by muse, mutect2, varscan2
- TRERF1 | c.2773G>T p.V925L | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV61667725; called by muse, mutect2
- TRIP12 | c.4301A>T p.H1434L | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV99391142; called by mutect2, varscan2
- UBAP1L | c.481C>T p.R161W | Missense Mutation (SNP) | VAF 137/137 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs933188149; called by muse, mutect2, varscan2
- WDR7 | c.4364C>T p.A1455V | Missense Mutation (SNP) | VAF 101/101 reads (100%) | SIFT tolerated (0.64); PolyPhen benign (0.181); catalogued as rs750926404; called by muse, mutect2, varscan2
- ZNF251 | c.934C>T p.R312W | Missense Mutation (SNP) | VAF 121/211 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs200114017; called by muse, mutect2, varscan2
- ZNF747 | c.560C>T p.P187L | Missense Mutation (SNP) | VAF 318/589 reads (54%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as rs890550251, COSV53224406; called by muse, mutect2, varscan2
- APC | c.3209del p.N1070Ifs*56 | Frame Shift Del (DEL) | VAF 125/280 reads (45%) | called by mutect2, pindel, varscan2
- APOB | c.10788G>T p.M3596I | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AQP11 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- CARMIL1 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CCNA1 | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 6/141 reads (4%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0.007); called by muse, mutect2
- CEP85L | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- CLASP2 | c.4067C>G p.A1356G (on ENST00000359576; = p.A1355G on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/116 reads (63%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- COL6A5 | c.2828A>G p.N943S | Missense Mutation (SNP) | VAF 225/360 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- CRYBG3 | c.3396T>G p.Y1132* | Nonsense Mutation (SNP) | VAF 16/96 reads (17%) | called by muse, mutect2, varscan2
- CTNNA3 | c.1652T>A p.V551D | Missense Mutation (SNP) | VAF 71/375 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CUBN | c.2720A>C p.Y907S | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DACT2 | c.2024dup p.S676Vfs*13 | Frame Shift Ins (INS) | VAF 64/170 reads (38%) | called by mutect2, pindel, varscan2
- DDHD2 | c.1634A>C p.Y545S | Missense Mutation (SNP) | VAF 36/247 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DGKI | c.2853T>A p.S951R | Missense Mutation (SNP) | VAF 17/231 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.258); called by muse, mutect2
- DRC7 | c.2306C>A p.A769E | Missense Mutation (SNP) | VAF 17/144 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EPHA5 | c.2107C>G p.P703A | Missense Mutation (SNP) | VAF 89/90 reads (99%) | SIFT tolerated (0.49); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAM217B | c.712C>A p.Q238K | Missense Mutation (SNP) | VAF 233/385 reads (61%) | SIFT tolerated (0.33); PolyPhen benign (0.385); called by muse, mutect2, varscan2
- FAM72B | c.256A>G p.I86V | Missense Mutation (SNP) | VAF 187/350 reads (53%) | SIFT tolerated (0.73); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXD4L5 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 110/662 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.12); called by mutect2, varscan2
- GARRE1 | c.2978G>T p.S993I | Missense Mutation (SNP) | VAF 44/151 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.264); called by muse, mutect2, varscan2
- GNG11 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- GPC2 | c.1559del p.P520Qfs*67 | Frame Shift Del (DEL) | VAF 12/104 reads (12%) | called by mutect2, pindel
- GPR45 | c.1045G>A p.V349M | Missense Mutation (SNP) | VAF 37/282 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- GRM1 | c.2975C>T p.P992L | Missense Mutation (SNP) | VAF 57/108 reads (53%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); called by muse, mutect2, varscan2
- HELZ | c.2752T>A p.F918I | Missense Mutation (SNP) | VAF 132/132 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- HHLA1 | c.1224del p.R409Dfs*58 | Frame Shift Del (DEL) | VAF 8/61 reads (13%) | called by mutect2, pindel, varscan2
- HTR3A | c.970A>G p.I324V | Missense Mutation (SNP) | VAF 189/329 reads (57%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.576); called by muse, varscan2
- INHBA | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 274/410 reads (67%) | SIFT tolerated (0.15); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ITGA9 | c.88T>A p.Y30N | Missense Mutation (SNP) | VAF 142/248 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ITGB3 | c.1279G>A p.A427T | Missense Mutation (SNP) | VAF 230/558 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- JHY | c.2107A>G p.T703A | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1549 | c.811G>C p.A271P | Missense Mutation (SNP) | VAF 12/302 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2
- L3MBTL4 | c.37G>T p.D13Y | Missense Mutation (SNP) | VAF 71/71 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LRRC72 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.204); called by muse, mutect2, varscan2
- MAP1A | c.6785A>G p.E2262G | Missense Mutation (SNP) | VAF 357/358 reads (100%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.436); called by muse, mutect2, varscan2
- MDH1B | c.1164G>T p.W388C | Missense Mutation (SNP) | VAF 31/213 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- MYO1E | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 6/117 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NKTR | c.3205A>G p.K1069E | Missense Mutation (SNP) | VAF 62/106 reads (58%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NTM | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 140/243 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR8K1 | c.18A>C p.K6N | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- OR8K5 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 24/177 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PHYHIPL | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 79/305 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- PLCE1 | c.3660G>C p.E1220D | Missense Mutation (SNP) | VAF 127/561 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- PMEPA1 | c.475C>A p.P159T | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPP1CB | c.226G>T p.E76* | Nonsense Mutation (SNP) | VAF 45/89 reads (51%) | called by muse, mutect2, varscan2
- PPP2R1A | c.1180G>T p.V394L | Missense Mutation (SNP) | VAF 113/113 reads (100%) | SIFT deleterious (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PTP4A3 | c.178A>T p.K60* | Nonsense Mutation (SNP) | VAF 41/362 reads (11%) | called by muse, mutect2, varscan2
- PTPN13 | c.5693G>A p.C1898Y (on ENST00000411767 / NM_080683.3; = p.C1879Y on NM_006264.3) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- RTL4 | c.758A>T p.K253M | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- SATL1 | c.1502T>C p.L501P (on ENST00000395409; = p.L688P on NM_001367857.2) | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- SERPINB2 | c.497G>T p.R166I | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SH3RF3 | c.2255T>C p.V752A | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A4 | c.111G>A p.M37I | Missense Mutation (SNP) | VAF 154/309 reads (50%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SLIT1 | c.2627G>A p.W876* | Nonsense Mutation (SNP) | VAF 135/269 reads (50%) | called by muse, mutect2, varscan2
- SMG1 | c.9077T>A p.L3026Q | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SPART | c.236A>G p.Q79R | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- SSBP4 | c.16G>C p.G6R | Missense Mutation (SNP) | VAF 44/92 reads (48%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- SSC5D | c.2251T>C p.S751P | Missense Mutation (SNP) | VAF 49/49 reads (100%) | SIFT tolerated (0.11); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SYNE1 | c.4099T>A p.L1367M (on ENST00000367255 / NM_182961.4; = p.L1374M on NM_033071.3) | Missense Mutation (SNP) | VAF 22/141 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TEX51 | c.48G>T p.K16N | Missense Mutation (SNP) | VAF 79/138 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- TOGARAM1 | c.1859A>G p.Q620R | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- USP48 | c.2680A>G p.K894E | Missense Mutation (SNP) | VAF 165/165 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- UST | c.777C>A p.C259* | Nonsense Mutation (SNP) | VAF 88/188 reads (47%) | called by muse, mutect2
- WDR6 | c.3111_3113dup p.E1037_Y1038ins* | Nonsense Mutation (INS) | VAF 61/229 reads (27%) | called by mutect2, pindel, varscan2
- XRN2 | c.298A>G p.M100V | Missense Mutation (SNP) | VAF 6/104 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); called by muse, mutect2
- ZRANB3 | c.125A>T p.K42I | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ABCA13 | c.15117T>C p.T5039= | Silent (SNP) | VAF 36/431 reads (8%) | catalogued as COSV68944224; called by muse, mutect2
- ABCG4 | c.78C>T p.D26= | Silent (SNP) | VAF 91/302 reads (30%) | catalogued as rs373824430; called by muse, mutect2, varscan2
- AC138647.1 | c.438G>A p.A146= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs1017846341; called by muse, mutect2, varscan2
- ADAMTSL1 | c.1791G>A p.G597= | Silent (SNP) | VAF 119/280 reads (43%) | called by muse, mutect2, varscan2
- ANKEF1 | c.1071C>T p.N357= | Silent (SNP) | VAF 81/194 reads (42%) | catalogued as rs937679166; called by muse, mutect2, varscan2
- APOBEC3F | c.708C>T p.G236= | Silent (SNP) | VAF 50/128 reads (39%) | catalogued as COSV57910186; called by muse, mutect2
- ARHGAP24 | c.96T>C p.F32= | Silent (SNP) | VAF 29/104 reads (28%) | called by muse, mutect2, varscan2
- ASAP1 | c.3021C>A p.V1007= | Silent (SNP) | VAF 36/343 reads (10%) | called by muse, mutect2, varscan2
- ATP5PB | c.489C>A p.R163= | Silent (SNP) | VAF 24/91 reads (26%) | called by muse, mutect2, varscan2
- CDK14 | c.1269G>A p.P423= (on ENST00000380050 / NM_001287135.2; = p.P405= on NM_012395.3) | Silent (SNP) | VAF 28/230 reads (12%) | catalogued as rs775794454, COSV56045220; called by muse, mutect2, varscan2
- CTNNA2 | c.351G>A p.S117= | Silent (SNP) | VAF 168/330 reads (51%) | catalogued as rs201020471, COSV63548922; called by muse, mutect2, varscan2
- CYP2D6 | c.264C>T p.R88= | Silent (SNP) | VAF 287/1125 reads (26%) | catalogued as rs1230147351; called by muse, mutect2, varscan2
- DAB2 | c.1386C>T p.P462= | Silent (SNP) | VAF 101/208 reads (49%) | catalogued as rs1232950773, COSV57917425; called by muse, mutect2, varscan2
- DPP10 | c.1321C>T p.L441= | Silent (SNP) | VAF 33/81 reads (41%) | called by muse, mutect2, varscan2
- FAM161A | c.90C>T p.Y30= | Silent (SNP) | VAF 218/469 reads (46%) | called by muse, mutect2, varscan2
- FAM227A | c.639G>A p.Q213= | Silent (SNP) | VAF 85/151 reads (56%) | called by muse, mutect2, varscan2
- FAT3 | c.11919G>A p.T3973= | Silent (SNP) | VAF 162/295 reads (55%) | catalogued as rs898299684, COSV53101021; called by muse, mutect2, varscan2
- FOXO1 | c.1746C>T p.S582= | Silent (SNP) | VAF 107/142 reads (75%) | called by muse, mutect2, varscan2
- GAB4 | c.72G>A p.S24= | Silent (SNP) | VAF 71/201 reads (35%) | catalogued as rs1182743180; called by muse, mutect2, varscan2
- GALNT14 | c.1587C>T p.N529= | Silent (SNP) | VAF 123/264 reads (47%) | catalogued as rs145219116; called by muse, mutect2, varscan2
- GAS1 | c.957C>T p.G319= | Silent (SNP) | VAF 44/267 reads (16%) | catalogued as rs1277031413; called by muse, mutect2, varscan2
- GATA5 | c.675G>A p.P225= | Silent (SNP) | VAF 171/587 reads (29%) | catalogued as rs144082730; called by muse, mutect2, varscan2
- GGT6 | c.780C>T p.S260= (on ENST00000574154 / NM_001122890.3; = p.S228= on NM_153338.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/165 reads (64%) | catalogued as rs768266892, COSV99626686; called by muse, mutect2, varscan2
- HECW2 | c.1914G>A p.L638= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as COSV53651191; called by muse, mutect2, varscan2
- IGKV1D-13 | c.132T>C p.T44= | Silent (SNP) | VAF 58/524 reads (11%) | called by muse, mutect2, varscan2
- LIFR | c.1080G>A p.A360= | Silent (SNP) | VAF 81/278 reads (29%) | catalogued as rs769294023, COSV99665244; ClinVar: likely benign; called by muse, mutect2, varscan2
- LMNB1 | c.1332C>T p.I444= | Silent (SNP) | VAF 149/250 reads (60%) | catalogued as rs779989576; called by muse, mutect2, varscan2
- MARCHF11 | c.297C>T p.A99= | Silent (SNP) | VAF 7/45 reads (16%) | called by muse, mutect2, varscan2
- MC2R | c.504C>T p.F168= | Silent (SNP) | VAF 120/121 reads (99%) | called by muse, mutect2, varscan2
- MESP1 | c.231C>T p.S77= | Silent (SNP) | VAF 103/103 reads (100%) | called by muse, mutect2, varscan2
- MUC17 | c.765A>T p.S255= | Silent (SNP) | VAF 20/208 reads (10%) | called by muse, mutect2
- MYT1L | c.816C>T p.H272= | Silent (SNP) | VAF 117/217 reads (54%) | catalogued as rs751168400, COSV67728872; called by muse, mutect2, varscan2
- NKTR | c.18G>A p.R6= | Silent (SNP) | VAF 14/198 reads (7%) | called by muse, mutect2
- NPL | c.324C>T p.I108= | Silent (SNP) | VAF 197/327 reads (60%) | catalogued as rs369901524; called by muse, mutect2, varscan2
- OCM2 | c.15C>T p.D5= | Silent (SNP) | VAF 52/275 reads (19%) | catalogued as rs762988500, COSV57535963; called by muse, varscan2
- OR5D14 | c.346T>C p.L116= | Silent (SNP) | VAF 13/119 reads (11%) | catalogued as COSV59456317; called by muse, mutect2, varscan2
- PIK3C2G | c.2052A>G p.R684= (on ENST00000676171; = p.R643= on NM_004570.5) | Silent (SNP) | VAF 16/79 reads (20%) | called by muse, mutect2, varscan2
- PLXNB2 | c.660G>A p.A220= | Silent (SNP) | VAF 45/333 reads (14%) | catalogued as rs764104950, COSV63785608; called by muse, mutect2, varscan2
- PPT1 | c.363G>A p.R121= (on ENST00000433473; = p.R122= on NM_000310.4) | Silent (SNP) | VAF 249/250 reads (100%) | called by muse, mutect2, varscan2
- PRADC1 | c.237C>T p.N79= | Silent (SNP) | VAF 70/420 reads (17%) | catalogued as rs753244246; called by muse, mutect2, varscan2
- PROKR2 | c.420C>T p.Y140= | Silent (SNP) | VAF 109/234 reads (47%) | catalogued as rs199794008, CM085658; called by muse, mutect2, varscan2
- RAET1E | c.39T>A p.L13= | Silent (SNP) | VAF 35/249 reads (14%) | called by muse, mutect2, varscan2
- SNRNP200 | c.4353C>T p.F1451= | Silent (SNP) | VAF 78/591 reads (13%) | catalogued as rs762245805, COSV60488816; called by muse, mutect2, varscan2
- SOX8 | c.915C>T p.G305= | Silent (SNP) | VAF 88/217 reads (41%) | catalogued as rs372544446, COSV53509080, COSV53510314; called by muse, mutect2
- TET2 | c.4224A>C p.G1408= | Silent (SNP) | VAF 4/25 reads (16%) | called by muse, varscan2
- TRIM72 | c.672G>A p.K224= | Silent (SNP) | VAF 46/185 reads (25%) | catalogued as rs970281310; called by muse, mutect2, varscan2
- TRPM2 | c.2292G>A p.P764= | Silent (SNP) | VAF 106/146 reads (73%) | catalogued as rs148173972; called by muse, mutect2, varscan2
- TRPM3 | c.4848C>G p.S1616= (on ENST00000357533 / NM_001366142.2; = p.S1471= on NM_020952.6) | Silent (SNP) | VAF 40/154 reads (26%) | called by muse, mutect2, varscan2
- UNC80 | c.5199C>A p.I1733= | Silent (SNP) | VAF 30/150 reads (20%) | catalogued as rs761133552; called by muse, mutect2, varscan2
- USP2 | c.705G>A p.T235= | Silent (SNP) | VAF 15/32 reads (47%) | catalogued as rs752095300, COSV52730776; called by muse, mutect2
- WDR13 | c.456G>A p.T152= | Silent (SNP) | VAF 176/176 reads (100%) | catalogued as rs1556993839; called by muse, mutect2, varscan2
- ABI3BP | c.1576+16724A>G | Intron (SNP) | VAF 24/237 reads (10%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915197 C>A | 5'Flank (SNP) | VAF 24/227 reads (11%) | catalogued as rs1235396957; called by muse, mutect2, varscan2
- C9orf62 | n.511G>T | RNA (SNP) | VAF 129/217 reads (59%) | catalogued as rs1011518817; called by muse, mutect2, varscan2
- CDH13 | c.45+77971T>C | Intron (SNP) | VAF 24/129 reads (19%) | called by muse, mutect2, varscan2
- CGB8 | c.-12G>T | 5'UTR (SNP) | VAF 135/137 reads (99%) | catalogued as rs200172544; called by muse, mutect2, varscan2
- CPNE2 | c.928-520C>T | Intron (SNP) | VAF 116/223 reads (52%) | called by muse, mutect2, varscan2
- EEF2KMT | c.96+364G>C | Intron (SNP) | VAF 8/85 reads (9%) | called by muse, mutect2, varscan2
- ESR1 | c.-14C>T | 5'UTR (SNP) | VAF 74/473 reads (16%) | catalogued as rs369069476; called by muse, mutect2, varscan2
- FSHB | c.-1G>A | 5'UTR (SNP) | VAF 89/261 reads (34%) | called by muse, mutect2, varscan2
- GALC | c.195+606C>T | Intron (SNP) | VAF 88/342 reads (26%) | called by muse, mutect2, varscan2
- IKBKB | c.1516+42T>G | Intron (SNP) | VAF 222/370 reads (60%) | called by muse, mutect2, varscan2
- KLF6 | c.*757A>G | 3'UTR (SNP) | VAF 7/89 reads (8%) | called by muse, mutect2
- LINC01001 | n.351C>T | RNA (SNP) | VAF 12/82 reads (15%) | called by muse, varscan2
- LINGO3 | c.-6C>T | 5'UTR (SNP) | VAF 13/113 reads (12%) | catalogued as rs1203618845; called by muse, mutect2
- LYNX1-SLURP2 | c.*186C>G | 3'UTR (SNP) | VAF 88/260 reads (34%) | called by muse, mutect2, varscan2
- MYH6 | c.4175+260G>T | Intron (SNP) | VAF 14/105 reads (13%) | catalogued as rs750630134; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.-23G>A | 5'UTR (SNP) | VAF 217/495 reads (44%) | called by muse, mutect2, varscan2
- PLCG2 | c.2307+89C>A | Intron (SNP) | VAF 96/249 reads (39%) | called by muse, mutect2, varscan2
- PPP2R5E | c.354+16del | Intron (DEL) | VAF 9/57 reads (16%) | catalogued as rs1566714124; called by mutect2, pindel, varscan2
- RUVBL2 | c.663+28C>T | Intron (SNP) | VAF 45/76 reads (59%) | catalogued as rs760748718; called by muse, mutect2, varscan2
- SFXN5 | c.945+4098C>T | Intron (SNP) | VAF 101/218 reads (46%) | catalogued as rs1037813559; called by muse, mutect2, varscan2
- SPEF2 | c.4448-3057G>C | Intron (SNP) | VAF 32/241 reads (13%) | called by muse, mutect2, varscan2
- THAP7 | chr22:21003014 C>A | 5'Flank (SNP) | VAF 41/220 reads (19%) | called by muse, mutect2, varscan2
- TMEM120A | c.*67C>T | 3'UTR (SNP) | VAF 130/175 reads (74%) | catalogued as rs782267943; called by muse, mutect2, varscan2
- TRAF7 | c.1386+30G>A | Intron (SNP) | VAF 55/200 reads (28%) | called by muse, mutect2, varscan2
- UQCRB | c.*2242T>G | 3'UTR (SNP) | VAF 26/272 reads (10%) | called by muse, mutect2, varscan2
- XIRP2 | c.*1400G>T | 3'UTR (SNP) | VAF 20/192 reads (10%) | catalogued as COSV99744746; called by muse, varscan2
- ZNF720 | c.361+1069T>G | Intron (SNP) | VAF 9/44 reads (20%) | called by muse, mutect2, varscan2
